Somatic mutation profile of tumor specimen TCGA-B5-A1MR-01A (aliquot TCGA-B5-A1MR-01A-31D-A14G-09) from TCGA case TCGA-B5-A1MR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.8 years (24,017 days).
Specimen TCGA-B5-A1MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44776f7d-9a82-476b-b462-492148d3d546.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MR-10A (Blood Derived Normal), aliquot TCGA-B5-A1MR-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1394cf11-3b2a-4047-b332-4f760d9972ba

The open-access MAF lists 5,652 somatic variants for this specimen: 4,471 protein-altering or splice-affecting, 1,029 silent, 152 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,873, Silent 1,029, Nonsense Mutation 477, Splice Site 72, RNA 54, Intron 53, Splice Region 23, 3'UTR 18, 5'Flank 12, Frame Shift Ins 10, 3'Flank 10, Nonstop Mutation 6.

Variants (750 of 5,652; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1559183717, CM081493, COSV55602700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTK | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs128620187, CM940182, COSV58118363; ClinVar: pathogenic; called by mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by mutect2, varscan2
- DEGS1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367958450, COSV60379003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs1557320151, CM098412, COSV63744696; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs373585652, CM052862; ClinVar: pathogenic; called by mutect2, varscan2
- GATA6 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs387906819, CM1110614, COSV52524456; ClinVar: pathogenic; called by mutect2, varscan2
- HSD3B2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs80358219, CM930411; ClinVar: pathogenic; called by mutect2, varscan2
- MAPT | c.2231C>T p.S744L (on ENST00000262410 / NM_001377265.1; = p.S352L on NM_005910.5) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs63750425, CM034824, COSV52241355; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039204, CM074943, COSV62522274; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064793206, COSV62517574; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by mutect2, varscan2
- RBCK1 | c.1411G>A p.E471K (on ENST00000356286 / NM_031229.4; = p.E429K on NM_006462.6) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1342598444, COSV100675967; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RNF168 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as rs148275050, COSV58839007; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs367958902, CM020795; ClinVar: pathogenic; called by mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99257715; called by muse, mutect2
- A2M | c.4238A>G p.N1413S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs759894055, COSV100589015; called by mutect2, varscan2
- A2ML1 | c.2967G>T p.E989D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV100229456; called by mutect2, varscan2
- A4GALT | c.235A>C p.I79L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV99966767; called by mutect2, varscan2
- AADAC | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as COSV99233506; called by muse, mutect2, varscan2
- AADACL4 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV66107132; called by mutect2, varscan2
- ABCA1 | c.2656A>C p.I886L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101037635; called by muse, mutect2, varscan2
- ABCA10 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as rs1386874174, COSV99289333; called by muse, mutect2
- ABCA10 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs756825645, COSV99289335; called by mutect2, varscan2
- ABCA12 | c.5728G>T p.D1910Y (on ENST00000272895 / NM_173076.3; = p.D1592Y on NM_015657.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55967627; called by mutect2, varscan2
- ABCA13 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70049212; called by muse, varscan2
- ABCA13 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs989980736, COSV101330176; called by muse, mutect2, varscan2
- ABCA13 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.311); catalogued as COSV101330177; called by mutect2, varscan2
- ABCA13 | c.2608A>C p.S870R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs757208845, COSV101330178; called by mutect2, varscan2
- ABCA13 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs993284068, COSV101330122, COSV101330179; called by mutect2, varscan2
- ABCA13 | c.4306A>C p.K1436Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV101330181; called by muse, mutect2
- ABCA13 | c.5398G>A p.D1800N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV101330182; called by muse, mutect2, varscan2
- ABCA13 | c.5797A>C p.N1933H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70032487; called by muse, mutect2
- ABCA13 | c.7264G>A p.E2422K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as COSV101447209; called by mutect2, varscan2
- ABCA13 | c.8725A>C p.S2909R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV101447210; called by muse, mutect2, varscan2
- ABCA13 | c.10981G>A p.V3661I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1219552859, COSV101447212; called by muse, mutect2, varscan2
- ABCA6 | c.4147G>A p.G1383R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447679; called by muse, mutect2, varscan2
- ABCA9 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60623092; called by mutect2, varscan2
- ABCB1 | c.2090T>G p.F697C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99714347; called by muse, mutect2
- ABCB1 | c.1877T>C p.V626A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); catalogued as COSV99714351; called by muse, mutect2
- ABCB1 | c.1650G>T p.K550N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99714353; called by mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs1222604496, COSV55945529; called by muse, mutect2, varscan2
- ABCB1 | c.575T>C p.M192T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV99714359; called by muse, mutect2, varscan2
- ABCB11 | c.1086T>G p.I362M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99793053; called by muse, varscan2
- ABCB11 | c.706T>G p.F236V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99793060; called by muse, mutect2
- ABCB5 | c.1704G>T p.E568D (on ENST00000404938 / NM_001163941.2; = p.E123D on NM_178559.6) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV51721380; called by mutect2, varscan2
- ABCC10 | c.3247C>T p.R1083C (on ENST00000372530 / NM_001198934.2; = p.R1055C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.567); catalogued as rs41281804; called by mutect2, varscan2
- ABCC10 | c.4012C>T p.R1338W (on ENST00000372530 / NM_001198934.2; = p.R1310W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199697720, COSV99767964; called by mutect2, varscan2
- ABCC12 | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139931213; called by mutect2, varscan2
- ABCC12 | c.2133A>C p.E711D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100253222; called by muse, mutect2, varscan2
- ABCC12 | c.1362G>T p.K454N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV60911926, COSV60913332; called by muse, mutect2, varscan2
- ABCC2 | c.1266C>A p.N422K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100966709; called by muse, mutect2, varscan2
- ABCC4 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs771698317, COSV65318332; called by mutect2, varscan2
- ABCC5 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs550542220, COSV55589847, COSV55597043; called by muse, mutect2, varscan2
- ABCC8 | c.4127T>C p.I1376T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100217723; called by muse, mutect2, varscan2
- ABCC9 | c.3338C>A p.S1113Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.516); catalogued as COSV99687197; called by mutect2, varscan2
- ABCE1 | c.1247T>G p.I416S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56849160; called by muse, mutect2, varscan2
- ABHD11 | c.837T>G p.I279M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as COSV99766934; called by muse, mutect2, varscan2
- ABI3BP | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs373865185; called by muse, mutect2, varscan2
- ABI3BP | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52527951; called by mutect2, varscan2
- ABRAXAS1 | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100426984; called by muse, mutect2, varscan2
- AC004922.1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764232067, COSV99403106; called by mutect2, varscan2
- AC013477.1 | c.2403G>T p.Q801H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99549100; called by muse, mutect2, varscan2
- AC090517.4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as rs774201353, COSV50996219; called by mutect2, varscan2
- AC090517.4 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50996010; called by mutect2, varscan2
- AC098582.1 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV99986025; called by muse, varscan2
- AC098582.1 | c.1316G>T p.S439I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99986026; called by muse, mutect2
- AC100868.1 | c.728A>C p.K243T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99226873; called by muse, mutect2, varscan2
- ACAD10 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100564592; called by muse, varscan2
- ACADSB | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs368438650, COSV62551325; called by mutect2, varscan2
- ACAP2 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100462720; called by muse, mutect2, varscan2
- ACCSL | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV101122295; called by muse, mutect2, varscan2
- ACE2 | c.1972G>T p.V658L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV99383097; called by mutect2, varscan2
- ACE2 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99383099; called by muse, mutect2, varscan2
- ACIN1 | c.3511C>T p.R1171* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99399405; called by muse, mutect2, varscan2
- ACO1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV100008628; called by muse, mutect2, varscan2
- ACOT4 | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412951; called by mutect2, varscan2
- ACOX1 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV53131966; called by mutect2, varscan2
- ACOX3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141372938, COSV99067070; called by mutect2, varscan2
- ACOXL | c.1362T>G p.I454M (on ENST00000389811 / NM_001371254.1; = p.I424M on NM_001142807.4) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV101096115; called by muse, mutect2, varscan2
- ACRBP | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV99976288; called by muse, mutect2, varscan2
- ACSBG2 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99397647; called by muse, mutect2, varscan2
- ACSL5 | c.1058G>A p.R353Q (on ENST00000354273; = p.R409Q on NM_016234.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759733603, COSV100634804; called by mutect2, varscan2
- ACSM2B | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100313118, COSV100313155; called by muse, mutect2, varscan2
- ACSM2B | c.1625G>T p.R542I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313119, COSV61656919; called by muse, mutect2, varscan2
- ACSM4 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748592689, COSV101257385, COSV68067084; called by mutect2, varscan2
- ACSS2 | c.1251G>T p.M417I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV53627021, COSV99490211; called by muse, mutect2, varscan2
- ACTR10 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99581360; called by muse, mutect2, varscan2
- ACTR2 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99574130; called by muse, mutect2, varscan2
- ACTR3 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV99603992; called by muse, mutect2, varscan2
- ACTR5 | c.606-1G>T p.X202_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV54760798; called by muse, varscan2
- ACTRT1 | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947759; called by mutect2, varscan2
- ACYP1 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53135311; called by muse, mutect2, varscan2
- ADA2 | c.1177G>A p.A393T (on ENST00000262607; = p.A152T on NM_177405.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.402); catalogued as rs746332176, COSV99376464; called by mutect2, varscan2
- ADAD1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs267600006, COSV56642693; called by mutect2, varscan2
- ADAL | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.438); catalogued as COSV101052575; called by muse, mutect2, varscan2
- ADAM10 | c.321T>G p.I107M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99546638; called by muse, mutect2, varscan2
- ADAM22 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV55969681; called by muse, mutect2, varscan2
- ADAM23 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148692770, COSV52225138; called by mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMTS19 | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774154487; called by mutect2, varscan2
- ADAMTS8 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.37); catalogued as rs761177774, COSV99961029; called by mutect2, varscan2
- ADAMTS9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.076); catalogued as rs773453319, COSV55790673; called by mutect2, varscan2
- ADAMTSL1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs749737333, COSV52808094, COSV99444781; called by mutect2, varscan2
- ADAMTSL1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201796434, COSV99444789; called by mutect2, varscan2
- ADARB1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs771477217, COSV100654123; called by mutect2, varscan2
- ADAT2 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99395927; called by mutect2, varscan2
- ADCY2 | c.2697T>G p.F899L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100604094; called by muse, mutect2, varscan2
- ADCY8 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs753061333, COSV53930024; called by mutect2, varscan2
- ADCY8 | c.2391C>A p.F797L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV53897529, COSV99654296; called by muse, mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by mutect2, varscan2
- ADD3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV53325707; called by mutect2, varscan2
- ADGRA2 | c.1418T>G p.F473C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100178414; called by muse, mutect2, varscan2
- ADGRA3 | c.2961A>C p.E987D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.416); catalogued as COSV99293782; called by muse, mutect2, varscan2
- ADGRA3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1165791849, COSV51563231; called by mutect2, varscan2
- ADGRB3 | c.1871G>T p.R624I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65391216, COSV65405921; called by mutect2, varscan2
- ADGRF1 | c.2628C>A p.F876L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV99347601; called by muse, varscan2
- ADGRF2 | c.835G>T p.D279Y (on ENST00000296862 / NM_001368115.2; = p.D211Y on NM_153839.7) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99731752; called by mutect2, varscan2
- ADGRF4 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99348969; called by mutect2, varscan2
- ADGRG2 | c.2212T>C p.F738L (on ENST00000379869 / NM_001079858.3; = p.F735L on NM_005756.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100492672; called by muse, mutect2, varscan2
- ADGRG2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100492676; called by muse, mutect2, varscan2
- ADGRG4 | c.5996C>A p.S1999Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); catalogued as COSV99796741; called by muse, mutect2, varscan2
- ADGRG4 | c.6936G>T p.Q2312H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99796747; called by muse, mutect2, varscan2
- ADGRG6 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs748239263, COSV51592160; called by mutect2, varscan2
- ADGRG7 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV56300428; called by muse, mutect2, varscan2
- ADGRL3 | c.2469A>T p.L823F (on ENST00000506720 / NM_001322402.2; = p.L755F on NM_015236.6) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101547387; called by muse, mutect2
- ADGRV1 | c.3507C>A p.F1169L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV101316494; called by muse, varscan2
- ADGRV1 | c.7593C>A p.F2531L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV101316495; called by mutect2, varscan2
- ADGRV1 | c.9860C>A p.S3287* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101315792, COSV101316496; called by muse, mutect2, varscan2
- ADGRV1 | c.10082C>A p.S3361Y | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as COSV101316497, COSV67992185; called by muse, mutect2, varscan2
- ADH1B | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100520873; called by muse, mutect2, varscan2
- ADH6 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99422868; called by muse, mutect2, varscan2
- ADNP2 | c.1625T>C p.V542A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100081201; called by muse, mutect2, varscan2
- ADNP2 | c.2232G>T p.E744D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV100081205; called by mutect2, varscan2
- ADRM1 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99442233; called by muse, mutect2, varscan2
- ADSL | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374047157; ClinVar: uncertain significance; called by mutect2, varscan2
- AFAP1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs752222681, COSV100632138; called by mutect2, varscan2
- AFF1 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100321049; called by mutect2, varscan2
- AFF4 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112871745, COSV54796199; called by mutect2, varscan2
- AFG1L | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.53); catalogued as COSV100934010; called by mutect2, varscan2
- AFG3L2 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302172; called by muse, mutect2
- AGAP6 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs1281196601, COSV100929156; called by muse, mutect2, varscan2
- AGBL1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs577916222, COSV101224207; called by mutect2, varscan2
- AGBL2 | c.2332G>T p.D778Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100101461; called by mutect2, varscan2
- AGL | c.2265G>T p.K755N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99650011; called by muse, mutect2, varscan2
- AGMAT | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101011820; called by muse, mutect2, varscan2
- AGO3 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs1244575080, COSV55790721, COSV55792811; called by muse, mutect2, varscan2
- AGO4 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100943082; called by muse, mutect2, varscan2
- AGPS | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as COSV51561384; called by muse, mutect2, varscan2
- AGTPBP1 | c.1520G>T p.R507I (on ENST00000357081 / NM_001330701.2; = p.R467I on NM_015239.2) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100430247; called by muse, varscan2
- AGTPBP1 | c.1469A>C p.K490T (on ENST00000357081 / NM_001330701.2; = p.K450T on NM_015239.2) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100430250; called by muse, varscan2
- AGTR2 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100903630; called by muse, mutect2, varscan2
- AGXT2 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51487506, COSV51490159; called by mutect2, varscan2
- AHCTF1 | c.2116C>A p.L706I (on ENST00000366508; = p.L680I on NM_015446.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.069); catalogued as COSV58250222; called by mutect2, varscan2
- AHCTF1 | c.314T>G p.F105C (on ENST00000366508; = p.F79C on NM_015446.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404414; called by muse, mutect2, varscan2
- AHCYL2 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100273741; called by mutect2, varscan2
- AHI1 | c.2485C>A p.L829I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99663701; called by muse, mutect2, varscan2
- AHNAK | c.11911G>T p.D3971Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99949536; called by muse, varscan2
- AHNAK | c.8502G>T p.K2834N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV57211328; called by mutect2, varscan2
- AHNAK | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949544; called by mutect2, varscan2
- AHNAK2 | c.17378A>G p.N5793S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.147); catalogued as COSV100318911; called by muse, mutect2, varscan2
- AHNAK2 | c.8773C>A p.L2925M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.255); catalogued as COSV100318914; called by muse, mutect2, varscan2
- AHRR | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as rs765433353, COSV100327991; called by muse, mutect2, varscan2
- AIDA | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100388455; called by muse, varscan2
- AIMP1 | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100786214; called by muse, mutect2, varscan2
- AJUBA | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV52985958, COSV99401188; called by muse, mutect2, varscan2
- AK9 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99572781, COSV99572819; called by muse, mutect2, varscan2
- AKAP13 | c.1702A>G p.T568A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV100774626; called by muse, mutect2
- AKAP13 | c.2338A>C p.I780L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100774632; called by muse, mutect2, varscan2
- AKAP13 | c.2902A>C p.I968L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100773964, COSV100774633; called by muse, mutect2
- AKAP3 | c.2406+1G>A p.X802_splice | Splice Site (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99962615; called by muse, mutect2, varscan2
- AKAP3 | c.631A>C p.N211H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV57414166; called by muse, mutect2, varscan2
- AKAP6 | c.4401T>G p.F1467L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV99804379; called by muse, mutect2, varscan2
- AKAP7 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99541793; called by mutect2, varscan2
- AKAP9 | c.4772G>T p.R1591I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663084; called by mutect2, varscan2
- AKAP9 | c.4887G>T p.E1629D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663085; called by mutect2, varscan2
- AKAP9 | c.5510G>T p.R1837I (on ENST00000359028; = p.R1805I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100663088; called by mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs771217988, COSV62341755; called by mutect2, varscan2
- AKNAD1 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV100645864; called by mutect2, varscan2
- AKR1C2 | c.627A>C p.K209N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV101060538; called by muse, mutect2, varscan2
- AKT2 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100251534; called by muse, mutect2
- AKT3 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99796665; called by muse, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by mutect2, varscan2
- ALDH1L2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV51554593; called by muse, mutect2, varscan2
- ALDH3A2 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99450265; called by muse, mutect2, varscan2
- ALDOB | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100878922; called by muse, mutect2, varscan2
- ALG1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99276006; called by mutect2, varscan2
- ALG10B | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100440005; called by muse, varscan2
- ALG11 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201526759, COSV73000831; called by mutect2, varscan2
- ALG13 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.031); catalogued as COSV52641111; called by muse, mutect2, varscan2
- ALG6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1287725303, CM098503, COSV99673505; ClinVar: uncertain significance; called by muse, varscan2
- ALG6 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99673510; called by muse, mutect2, varscan2
- ALKBH2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99980618; called by mutect2, varscan2
- ALKBH6 | c.119G>A p.R40Q (on ENST00000252984 / NM_001297701.2; = p.R68Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.041); catalogued as rs201735546, COSV53324572; called by mutect2, varscan2
- ALLC | c.655A>C p.N219H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV99378266; called by muse, mutect2, varscan2
- ALLC | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376178731, COSV52994643; called by mutect2, varscan2
- ALMS1 | c.6632C>A p.S2211Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357695377, COSV100043689; called by mutect2, varscan2
- ALOX5 | c.1206A>C p.R402S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100980193; called by muse, mutect2, varscan2
- ALPK2 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.177); catalogued as COSV100864801; called by mutect2, varscan2
- ALS2 | c.2504C>T p.T835I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99970055; called by muse, varscan2
- ALX4 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762975194, COSV100241299; called by mutect2, varscan2
- AMD1 | c.325-1G>T p.X109_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100924461, COSV64387244; called by muse, mutect2, varscan2
- AMFR | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99316224; called by muse, mutect2, varscan2
- AMMECR1 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53320018, COSV99467166; called by muse, mutect2, varscan2
- AMN | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100141583; called by mutect2, varscan2
- AMOTL2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs747545396, COSV99998318; called by mutect2, varscan2
- AMPD1 | c.1978C>A p.L660I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100815231; called by muse, varscan2
- AMPD1 | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815235; called by muse, mutect2, varscan2
- AMY2B | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100796494; called by muse, mutect2, varscan2
- ANAPC15 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV99921469; called by mutect2, varscan2
- ANAPC5 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99946474; called by muse, mutect2, varscan2
- ANGPT1 | c.906T>G p.I302M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99864182; called by muse, mutect2, varscan2
- ANGPT2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100291185; called by mutect2, varscan2
- ANGPTL3 | c.495+1G>T p.X165_splice | Splice Site (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99225968; called by muse, mutect2, varscan2
- ANK2 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs751513548, COSV52156051; ClinVar: uncertain significance; called by mutect2, varscan2
- ANK3 | c.6729G>T p.E2243D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55053935, COSV99782299; called by mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs142673853, COSV55052053; called by mutect2, varscan2
- ANKAR | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs781375783, COSV55610933; called by mutect2, varscan2
- ANKRA2 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV99707131; called by muse, mutect2, varscan2
- ANKRD13A | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV99924122; called by muse, mutect2, varscan2
- ANKRD26 | c.3374A>G p.Y1125C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101063403; called by muse, varscan2
- ANKRD26 | c.2552T>G p.L851W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV101063407; called by muse, mutect2
- ANKRD30A | c.2734G>T p.E912* (on ENST00000611781; = p.E856* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | catalogued as COSV100654431, COSV64611307; called by muse, mutect2, varscan2
- ANKRD30A | c.3042G>T p.E1014D (on ENST00000611781; = p.E958D on NM_052997.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV100654410; called by muse, varscan2
- ANKRD34B | c.379A>C p.N127H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV58613689; called by muse, mutect2
- ANKRD35 | c.1755G>T p.E585D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV100841852; called by mutect2, varscan2
- ANKRD36 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101347539; called by muse, mutect2, varscan2
- ANKRD36B | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1356807816, COSV99308576; called by muse, mutect2, varscan2
- ANKRD39 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV101135746; called by muse, mutect2, varscan2
- ANKRD42 | c.1121A>C p.K374T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV99474169; called by muse, mutect2, varscan2
- ANKRD50 | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.036); catalogued as COSV101539047, COSV72385340; called by muse, mutect2
- ANKRD50 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as rs373734288, COSV101539048; called by mutect2, varscan2
- ANKRD7 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99501360; called by muse, mutect2, varscan2
- ANKS1B | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339675146, COSV100242639, COSV100245378, COSV100247839; called by muse, mutect2, varscan2
- ANLN | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99732869; called by mutect2, varscan2
- ANO2 | c.2100G>T p.K700N (on ENST00000356134 / NM_001278597.3; = p.K704N on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100502280; called by mutect2, varscan2
- ANO3 | c.1289+2T>G p.X430_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99885654; called by muse, mutect2, varscan2
- ANO6 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100263891, COSV57659106; called by muse, mutect2, varscan2
- ANO6 | c.2105A>G p.D702G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100263893; called by muse, mutect2
- ANP32B | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100233341; called by muse, mutect2, varscan2
- ANTXR2 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100226929; called by muse, mutect2
- ANXA13 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51624946, COSV99146946; called by muse, varscan2
- AOC1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs191291587, COSV100710987; called by mutect2, varscan2
- AOC1 | c.1960C>A p.L654I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV62867598; called by mutect2, varscan2
- AOX1 | c.2768T>G p.F923C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101022231; called by muse, mutect2, varscan2
- AOX1 | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV101022199; called by mutect2, varscan2
- AOX1 | c.3169C>A p.Q1057K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99613785; called by muse, varscan2
- AP1B1 | c.2844G>T p.K948N | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100434825; called by muse, mutect2, varscan2
- AP2B1 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV99251689; called by muse, mutect2, varscan2
- AP2B1 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV99251693; called by muse, varscan2
- AP3M1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs751432900, COSV53015672; called by mutect2, varscan2
- AP3S2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100318651; called by mutect2, varscan2
- AP4B1 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99871141; called by muse, mutect2, varscan2
- AP5M1 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs925328183, COSV55105033; called by mutect2, varscan2
- APAF1 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100141909; called by muse, mutect2, varscan2
- APBB3 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs760083930, COSV100021496; called by mutect2, varscan2
- APOB | c.6515C>A p.S2172Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51935566; called by mutect2, varscan2
- APOB | c.6218T>G p.F2073C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265760, COSV99268000; called by muse, mutect2, varscan2
- APOB | c.2716T>G p.F906V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99268003; called by muse, mutect2, varscan2
- APOBEC1 | c.600A>C p.Q200H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99981258; called by muse, mutect2, varscan2
- APOBEC2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.321); catalogued as rs1065197, COSV99775374; called by mutect2, varscan2
- APOBEC3D | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs1443766610, COSV99329187; called by mutect2, varscan2
- APOBEC3F | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100415264; called by muse, mutect2, varscan2
- APOF | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100029132; called by mutect2, varscan2
- APOL5 | c.1079G>T p.S360I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV99968465; called by muse, mutect2, varscan2
- APOM | c.443-1G>T p.X148_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99277614; called by mutect2, varscan2
- ARAF | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183909266, COSV51693440, COSV99283094; called by muse, mutect2, varscan2
- ARAP1 | c.4342C>T p.R1448C (on ENST00000393609 / NM_001040118.2; = p.R1203C on NM_015242.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs759390723, COSV100502191; called by muse, mutect2, varscan2
- ARAP2 | c.2941T>C p.F981L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.228); catalogued as COSV100395242; called by muse, mutect2, varscan2
- ARF4 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57714666, COSV57715913; called by muse, mutect2, varscan2
- ARFGEF1 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51613017; called by muse, varscan2
- ARFGEF1 | c.3485G>T p.R1162I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141462, COSV99144643; called by muse, varscan2
- ARFGEF1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99143108; called by muse, mutect2, varscan2
- ARFGEF1 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV99144664; called by muse, mutect2, varscan2
- ARFGEF3 | c.5178G>T p.Q1726H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV99294675; called by mutect2, varscan2
- ARGFX | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100544212; called by muse, mutect2, varscan2
- ARHGAP12 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100260892; called by muse, mutect2, varscan2
- ARHGAP12 | c.701A>C p.N234T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs558646264, COSV100260901; called by mutect2, varscan2
- ARHGAP17 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV99254039; called by mutect2, varscan2
- ARHGAP20 | c.2392C>A p.P798T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); catalogued as COSV52818636, COSV99505332; called by mutect2, varscan2
- ARHGAP21 | c.4470G>T p.K1490N | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV100256651; called by muse, mutect2
- ARHGAP21 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100256653; called by muse, mutect2, varscan2
- ARHGAP21 | c.2135G>T p.R712M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100256658, COSV57603433; called by muse, mutect2, varscan2
- ARHGAP26 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749597249, COSV50828807; called by muse, mutect2, varscan2
- ARHGAP31 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV99957724; called by mutect2, varscan2
- ARHGAP31 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1316151567, COSV99957727; called by mutect2, varscan2
- ARHGAP31 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775767431, COSV51789291, COSV51793206; called by muse, mutect2, varscan2
- ARHGAP32 | c.5497G>A p.E1833K (on ENST00000310343 / NM_001378025.1; = p.E1484K on NM_014715.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs750421315, COSV100089264; called by mutect2, varscan2
- ARHGAP32 | c.5059C>T p.R1687* (on ENST00000310343 / NM_001378025.1; = p.R1338* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100089267; called by mutect2, varscan2
- ARHGAP32 | c.3462A>C p.Q1154H (on ENST00000310343 / NM_001378025.1; = p.Q805H on NM_014715.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100089270; called by muse, mutect2, varscan2
- ARHGAP45 | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100491108; called by mutect2, varscan2
- ARHGAP5 | c.2533G>T p.D845Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100565692; called by mutect2, varscan2
- ARHGAP5 | c.3916G>T p.D1306Y (on ENST00000345122 / NM_001030055.2; = p.D1305Y on NM_001173.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100565693; called by mutect2, varscan2
- ARHGAP6 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV100273560; called by muse, mutect2, varscan2
- ARHGEF15 | c.1865A>C p.K622T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100730161; called by mutect2, varscan2
- ARHGEF2 | c.689A>C p.K230T (on ENST00000361247 / NM_001162383.2; = p.K202T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100561163; called by muse, mutect2, varscan2
- ARHGEF26 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377732491; called by muse, mutect2, varscan2
- ARHGEF28 | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs1330051916, COSV55256931, COSV99710085; called by muse, mutect2, varscan2
- ARID1A | c.2870A>C p.N957T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100253374; called by mutect2, varscan2
- ARID1A | c.3326G>A p.R1109Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV61388306; called by muse, mutect2, varscan2
- ARID1A | c.5331A>C p.E1777D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100253377; called by mutect2, varscan2
- ARID1A | c.5710G>T p.E1904* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61372412; called by mutect2, varscan2
- ARID2 | c.708T>G p.F236L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100537017; called by muse, mutect2, varscan2
- ARID4B | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99936321; called by muse, mutect2, varscan2
- ARIH2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62704846; called by mutect2, varscan2
- ARL11 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99949219; called by mutect2, varscan2
- ARL11 | c.522A>C p.K174N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV99949221; called by muse, mutect2
- ARL14EP | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV56343888, COSV99956040; called by muse, mutect2
- ARL2 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99880685; called by muse, mutect2, varscan2
- ARL6IP4 | c.1198G>T p.E400* (on ENST00000315580 / NM_018694.3; = p.E381* on NM_016638.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99759637; called by mutect2, varscan2
- ARL6IP6 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV100424125; called by muse, mutect2, varscan2
- ARMC10 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.984); catalogued as COSV100085854; called by muse, mutect2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2, varscan2
- ARNT | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100591366; called by mutect2, varscan2
- ARNTL | c.1214A>C p.K405T (on ENST00000403290 / NM_001297719.2; = p.K404T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV62987700; called by muse, mutect2
- ARPP21 | c.2174C>A p.S725Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV51808302; called by muse, mutect2, varscan2
- ARRDC4 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs759457620, COSV51420299; called by muse, mutect2, varscan2
- ARRDC4 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs556598670, COSV51420619; called by mutect2, varscan2
- ARSF | c.1121del p.G374Afs*23 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs1158308642; called by mutect2, pindel, varscan2
- ARSI | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100156098; called by muse, mutect2, varscan2
- ART5 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV100731718; called by muse, mutect2, varscan2
- ASAP1 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV100727813; called by muse, mutect2, varscan2
- ASB13 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs924447941; called by mutect2, varscan2
- ASB5 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99642108; called by mutect2, varscan2
- ASB8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747598837, COSV58350916; called by mutect2, varscan2
- ASCC3 | c.5149C>A p.L1717I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1482481542, COSV100976913, COSV64975116; called by mutect2, varscan2
- ASGR1 | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352616; called by muse, mutect2, varscan2
- ASH1L | c.5781A>C p.K1927N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100853597; called by muse, mutect2
- ASH2L | c.1364A>C p.K455T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99167043; called by muse, mutect2, varscan2
- ASIC5 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV101611175; called by muse, mutect2, varscan2
- ASIC5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs145147748; called by mutect2, varscan2
- ASPH | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100727611; called by muse, mutect2, varscan2
- ASPM | c.3829T>G p.W1277G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661102; called by muse, mutect2, varscan2
- ASPM | c.1914G>T p.K638N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV54134711, COSV99661104; called by mutect2, varscan2
- ASPM | c.1605A>C p.Q535H | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99661105; called by muse, mutect2
- ASPM | c.1092A>C p.K364N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99661106; called by muse, mutect2
- ASTE1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as COSV99393992; called by mutect2, varscan2
- ASTN1 | c.334T>C p.W112R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99923036; called by muse, mutect2, varscan2
- ASXL1 | c.2684C>A p.S895Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV100040820; called by muse, mutect2, varscan2
- ASXL3 | c.4802A>G p.Y1601C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs1175802497, COSV99326530; called by muse, mutect2, varscan2
- ATAD2 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375014962, COSV54886467; called by muse, mutect2, varscan2
- ATAD2 | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99785274; called by muse, mutect2, varscan2
- ATAD5 | c.2357A>C p.K786T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100430215; called by muse, mutect2, varscan2
- ATE1 | c.1213T>G p.Y405D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99817700; called by muse, mutect2, varscan2
- ATE1 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs1382753781, COSV99817706; called by muse, mutect2, varscan2
- ATF4 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1012671336, COSV100307838; called by muse, mutect2, varscan2
- ATG10 | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99967306; called by mutect2, varscan2
- ATG16L1 | c.1063A>C p.K355Q (on ENST00000392017 / NM_030803.7; = p.K336Q on NM_017974.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV100731397; called by muse, mutect2, varscan2
- ATG16L1 | c.1191T>G p.D397E (on ENST00000392017 / NM_030803.7; = p.D378E on NM_017974.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100731399; called by muse, mutect2, varscan2
- ATG2B | c.2477T>G p.F826C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.996); catalogued as COSV100738244; called by muse, mutect2, varscan2
- ATL1 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100613314; called by muse, mutect2, varscan2
- ATM | c.3602T>G p.F1201C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CD991601, COSV99591863; called by muse, mutect2, varscan2
- ATP10D | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs767742740, COSV56708578; called by mutect2, varscan2
- ATP10D | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs376991791; called by mutect2, varscan2
- ATP11C | c.2182A>C p.K728Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV100558622; called by mutect2, varscan2
- ATP11C | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100558626; called by muse, varscan2
- ATP12A | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99518445; called by muse, varscan2
- ATP12A | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54513500, COSV54515319; called by muse, mutect2, varscan2
- ATP12A | c.2726A>G p.Y909C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.44); catalogued as COSV54519620; called by muse, mutect2
- ATP13A3 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99757639; called by muse, mutect2, varscan2
- ATP1A1 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV55191537, COSV99814772; called by muse, mutect2, varscan2
- ATP1A1 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99814774; called by muse, mutect2, varscan2
- ATP1A4 | c.2616C>A p.F872L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV63627414; called by mutect2, varscan2
- ATP2C1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146989; called by muse, mutect2, varscan2
- ATP2C1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100146990; called by muse, mutect2, varscan2
- ATP4A | c.2379G>T p.K793N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV52868031, COSV99383084; called by mutect2, varscan2
- ATP5F1C | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100184404; called by muse, mutect2, varscan2
- ATP5MD | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as COSV100428310; called by muse, mutect2, varscan2
- ATP5PB | c.769T>C p.*257Qext*14 | Nonstop Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100867653; called by muse, mutect2, varscan2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV65797151; called by mutect2, varscan2
- ATP6V0A1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141985511; called by mutect2, varscan2
- ATP6V0A2 | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV100377159; called by muse, mutect2
- ATP6V1A | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV56361224; called by mutect2, varscan2
- ATP6V1C1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1455268921, COSV67777243, COSV67778043; called by muse, mutect2, varscan2
- ATP8A2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99684209; called by muse, varscan2
- ATP8B2 | c.443C>T p.S148F (on ENST00000672630; = p.S115F on NM_001005855.2) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV100528232, COSV59245976; called by muse, mutect2, varscan2
- ATP8B4 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99467449; called by muse, mutect2, varscan2
- ATP9A | c.2699C>T p.S900L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs1414033630, COSV100125613; called by muse, mutect2, varscan2
- ATP9A | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100125614; called by muse, mutect2, varscan2
- ATR | c.5328A>C p.E1776D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100638578; called by muse, varscan2
- ATRN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs535151003, COSV99496705; called by muse, mutect2, varscan2
- ATRX | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV64874759; called by mutect2, varscan2
- ATRX | c.4441C>T p.R1481W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100970390, COSV64880586; called by mutect2, varscan2
- ATRX | c.3154A>C p.K1052Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV100971424, COSV64873492; called by muse, mutect2, varscan2
- ATRX | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV100969630; called by muse, mutect2, varscan2
- ATXN10 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV99426733; called by muse, varscan2
- ATXN2 | c.2395A>G p.K799E (on ENST00000550104; = p.K639E on NM_002973.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101112906; called by muse, mutect2, varscan2
- ATXN2L | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57378398; called by muse, mutect2, varscan2
- ATXN3L | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as rs1279979260, COSV66075300; called by muse, mutect2, varscan2
- AUNIP | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as COSV100961952; called by muse, mutect2, varscan2
- AXDND1 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100858654; called by muse, varscan2
- AXDND1 | c.2017T>G p.F673V | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100858656; called by muse, mutect2
- AXIN1 | c.1895T>G p.I632S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99250302; called by mutect2, varscan2
- AXIN1 | c.1339T>G p.F447V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV99250304; called by muse, mutect2, varscan2
- AZI2 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99843765; called by muse, mutect2, varscan2
- AZIN1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.484); catalogued as COSV100457806; called by muse, mutect2, varscan2
- AZIN2 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99613782; called by mutect2, varscan2
- B3GALNT2 | c.1100T>G p.F367C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100782878; called by muse, mutect2
- B3GALT1 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV100002929; called by muse, mutect2, varscan2
- B3GALT2 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100813639; called by mutect2, varscan2
- B3GLCT | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58457299; called by muse, mutect2, varscan2
- B3GNT5 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV58475736; called by mutect2, varscan2
- B4GALNT2 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.038); catalogued as COSV100302765; called by muse, mutect2, varscan2
- B4GALT1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101123015; called by mutect2, varscan2
- B4GAT1 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756392214, COSV60819872; called by mutect2, varscan2
- BAAT | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as COSV52288144; called by muse, mutect2, varscan2
- BAAT | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.203); catalogued as COSV99408673; called by muse, mutect2, varscan2
- BACH2 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57584022; called by muse, mutect2, varscan2
- BATF2 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV100101893; called by muse, mutect2, varscan2
- BAZ1A | c.4193C>A p.S1398Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV100701213; called by mutect2, varscan2
- BAZ1B | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100289670, COSV100290132; called by muse, mutect2, varscan2
- BAZ2B | c.5391G>T p.L1797F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100600638, COSV100600997; called by mutect2, varscan2
- BAZ2B | c.1726A>C p.K576Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100600998; called by mutect2, varscan2
- BBS4 | c.333-1G>T p.X111_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99166537; called by muse, mutect2, varscan2
- BBS9 | c.1930G>T p.E644* (on ENST00000242067 / NM_001348036.1; = p.E604* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54178324; called by muse, mutect2, varscan2
- BCAN | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100228493; called by mutect2, varscan2
- BCAN | c.2728G>T p.G910C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV100228496; called by mutect2, varscan2
- BCKDK | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV99570866; called by mutect2, varscan2
- BCL2L13 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs577486545, COSV100456404; called by mutect2, varscan2
- BCL2L13 | c.1456T>C p.*486Qext*21 | Nonstop Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100456405; called by muse, mutect2
- BCLAF1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1487882129, COSV50361469; called by muse, mutect2, varscan2
- BCLAF3 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100503402; called by mutect2, varscan2
- BCO1 | c.592A>C p.I198L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs748236344, COSV99258647; called by mutect2, varscan2
- BCO2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764094222, COSV63062697, COSV63064809; called by mutect2, varscan2
- BCORL1 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as rs992482125, COSV99500893; called by mutect2, varscan2
- BCR | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100007045; called by muse, mutect2, varscan2
- BDP1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs751729367, COSV62432420; called by mutect2, varscan2
- BDP1 | c.4745A>C p.N1582T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100703514; called by muse, mutect2, varscan2
- BDP1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs746088956, COSV62432459; called by mutect2, varscan2
- BEST1 | c.147T>G p.I49M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV100077407; called by muse, mutect2, varscan2
- BEX1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101022510; called by mutect2, varscan2
- BFAR | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV99902458; called by mutect2, varscan2
- BICC1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99570891; called by muse, varscan2
- BICD2 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1273239213, COSV100794318; ClinVar: uncertain significance; called by mutect2, varscan2
- BIRC3 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99680230; called by mutect2, varscan2
- BIRC6 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV101428870; called by muse, mutect2, varscan2
- BIRC6 | c.3502C>A p.L1168I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV101428871; called by mutect2, varscan2
- BLMH | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV99913228; called by muse, mutect2
- BLMH | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV99913229; called by mutect2, varscan2
- BLNK | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV56413510; called by muse, mutect2, varscan2
- BMI1 | c.640A>T p.T214S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV100936501; called by muse, varscan2
- BMP2 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101122118; called by muse, mutect2, varscan2
- BMP2K | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372538499; called by mutect2, varscan2
- BMP2K | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as rs1281768189, COSV99785428; called by mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMP5 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100896355; called by mutect2, varscan2
- BMPER | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99780532; called by muse, mutect2
- BMPER | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99780534; called by mutect2, varscan2
- BNC1 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1270575850, COSV61757410; called by muse, mutect2, varscan2
- BOC | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV56346860, COSV56348417; called by mutect2, varscan2
- BOD1L1 | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99240404; called by muse, mutect2, varscan2
- BORA | c.1679T>C p.V560A (on ENST00000613797; = p.V485A on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as COSV64694779; called by muse, mutect2, varscan2
- BPIFA1 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100845658; called by muse, mutect2, varscan2
- BPIFA1 | c.318T>C p.I106= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100845659; called by muse, mutect2, varscan2
- BPIFB1 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV53608863, COSV99487608; called by muse, mutect2, varscan2
- BPIFC | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99322423; called by muse, mutect2, varscan2
- BPIFC | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV100301258; called by muse, mutect2, varscan2
- BRCA1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs55650082, CM1410357, COSV58783503; ClinVar: benign / likely benign; called by mutect2, varscan2
- BRCA2 | c.9431C>A p.S3144Y | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD111181, COSV101204640; called by muse, mutect2, varscan2
- BRD1 | c.3047A>G p.D1016G (on ENST00000216267 / NM_001349940.1; = p.D1147G on NM_001304808.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350281; called by muse, mutect2, varscan2
- BRD8 | c.2351T>C p.V784A (on ENST00000254900 / NM_139199.2; = p.V857A on NM_006696.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99137642; called by muse, mutect2
- BRDT | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV62863572, COSV62867237; called by mutect2, varscan2
- BRDT | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100746431, COSV100746587; called by muse, mutect2, varscan2
- BRPF1 | c.2971G>T p.D991Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100115575; called by mutect2, varscan2
- BRPF1 | c.3404C>T p.T1135I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV100115576; called by muse, mutect2, varscan2
- BRWD1 | c.4218A>C p.R1406S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV100314082; called by muse, mutect2, varscan2
- BRWD1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs199917402; called by mutect2, varscan2
- BRWD3 | c.5188G>T p.D1730Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100956530, COSV100956673; called by mutect2, varscan2
- BRWD3 | c.4729A>G p.S1577G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs891397261, COSV100956531; called by muse, mutect2, varscan2
- BRWD3 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100956533; called by muse, mutect2, varscan2
- BRWD3 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV64749640; called by muse, mutect2, varscan2
- BRWD3 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV100956535; called by mutect2, varscan2
- BSDC1 | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV100345085; called by muse, mutect2, varscan2
- BSN | c.11648C>A p.A3883D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99609804; called by muse, mutect2, varscan2
- BTAF1 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99795808; called by muse, mutect2, varscan2
- BTAF1 | c.4711-1G>T p.X1571_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56432267, COSV99795810; called by muse, mutect2, varscan2
- BTBD16 | c.835T>G p.L279V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99585275; called by muse, mutect2, varscan2
- BTD | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100329842; called by muse, mutect2, varscan2
- BTF3 | c.181C>A p.Q61K (on ENST00000380591 / NM_001037637.1; = p.Q17K on NM_001207.4) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100246735; called by muse, mutect2, varscan2
- BTK | c.273A>C p.Q91H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV100437917; called by muse, mutect2, varscan2
- BTRC | c.1385T>C p.L462S (on ENST00000370187 / NM_033637.4; = p.L426S on NM_003939.5) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927927; called by muse, mutect2, varscan2
- BUB1B | c.1507T>G p.C503G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99807301; called by mutect2, varscan2
- BUD23 | c.152A>C p.E51A | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as COSV99736914; called by muse, mutect2, varscan2
- BVES | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV100115124; called by mutect2, varscan2
- BZW1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV100729886, COSV63349594; called by muse, mutect2, varscan2
- C10orf71 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100110639; called by muse, mutect2, varscan2
- C11orf24 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100422702; called by muse, mutect2, varscan2
- C11orf65 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV67597759; called by muse, mutect2, varscan2
- C11orf80 | c.706T>G p.F236V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV100691126; called by muse, varscan2
- C12orf4 | c.789T>G p.I263M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99712931; called by muse, varscan2
- C12orf56 | c.1842T>G p.F614L (on ENST00000543942 / NM_001170633.2; = p.F454L on NM_001099676.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV100399831; called by muse, mutect2, varscan2
- C12orf56 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV100399834; called by muse, mutect2, varscan2
- C12orf66 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV100320912; called by mutect2, varscan2
- C14orf39 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100408121; called by muse, mutect2, varscan2
- C16orf70 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV99531643, COSV99531674; called by mutect2, varscan2
- C16orf72 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100589121; called by muse, mutect2, varscan2
- C16orf89 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301302453, COSV60122446; called by muse, mutect2
- C17orf78 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs755804849; called by muse, mutect2, varscan2
- C19orf57 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1282912452, COSV100694852, COSV60967046; called by muse, mutect2, varscan2
- C1QTNF9 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756266551, COSV100130023; called by mutect2, varscan2
- C1orf94 | c.1176G>T p.K392N (on ENST00000488417 / NM_001134734.2; = p.K202N on NM_032884.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs548017054, COSV64915638; called by mutect2, varscan2
- C2orf16 | c.47A>C p.E16A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as COSV101284421; called by muse, mutect2, varscan2
- C2orf16 | c.5557C>T p.H1853Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100821009; called by muse, mutect2, varscan2
- C3 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV55569757, COSV55570157, COSV99837235; called by muse, mutect2, varscan2
- C3orf20 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV53786967; called by muse, varscan2
- C3orf20 | c.2451G>T p.Q817H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99514549; called by muse, mutect2, varscan2
- C4B | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1438112943, COSV101426196; called by mutect2, varscan2
- C4BPA | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as COSV100891284; called by mutect2, varscan2
- C5 | c.4397C>T p.S1466L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs965313093, COSV99798707; called by muse, varscan2
- C5orf34 | c.336T>G p.D112E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV100175600; called by muse, mutect2
- C6orf118 | c.866A>C p.K289T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100025147; called by muse, mutect2
- C6orf58 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100315054; called by muse, varscan2
- C7 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761703740, COSV57473318; called by mutect2, varscan2
- C7orf31 | c.1740C>A p.F580L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV99384146, COSV99384164; called by muse, mutect2, varscan2
- C9orf131 | c.664T>G p.W222G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100398311; called by mutect2, varscan2
- CA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as rs373804439, COSV56277599; called by muse, mutect2, varscan2
- CA10 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs772993232, COSV53345738; called by mutect2, varscan2
- CA10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767808441, COSV53350762; called by mutect2, varscan2
- CA9 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100253523; called by mutect2, varscan2
- CABCOCO1 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100358084; called by muse, mutect2, varscan2
- CABIN1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99574000; called by mutect2, varscan2
- CABIN1 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as COSV99574002; called by muse, mutect2, varscan2
- CABIN1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as rs1368528246, COSV54080255; called by mutect2, varscan2
- CABYR | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs755150347, COSV100510176; called by mutect2, varscan2
- CACHD1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs761819776, COSV51547949; called by mutect2, varscan2
- CACNA1A | c.5230T>G p.F1744V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100803193; called by muse, mutect2, varscan2
- CACNA1B | c.3591G>T p.E1197D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99497965; called by muse, mutect2, varscan2
- CACNA1B | c.4930G>A p.A1644T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99499733; called by muse, mutect2, varscan2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2, varscan2
- CACNA1D | c.5113A>G p.N1705D (on ENST00000350061 / NM_001128840.3; = p.N1725D on NM_000720.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV99859982; called by muse, mutect2, varscan2
- CACNA1E | c.703T>C p.F235L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100705278; called by muse, mutect2, varscan2
- CACNA1E | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100701417; called by muse, mutect2, varscan2
- CACNA1E | c.3398T>G p.M1133R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100705283; called by muse, mutect2, varscan2
- CACNA1E | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV62381909; called by muse, varscan2
- CACNA1F | c.4637C>G p.A1546G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100545373; called by muse, mutect2, varscan2
- CACNA1G | c.4772A>C p.K1591T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV100662538; called by muse, mutect2, varscan2
- CACNA1I | c.4560G>T p.K1520N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100361520; called by muse, mutect2, varscan2
- CACNA1S | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV100755373; called by mutect2, varscan2
- CACNA2D1 | c.3110C>A p.T1037N (on ENST00000356253 / NM_001366867.1; = p.T1025N on NM_000722.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100667291; called by muse, mutect2, varscan2
- CACNA2D2 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs552824990, COSV99818342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99877004; called by mutect2, varscan2
- CACNA2D3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758120700, COSV55518521; called by mutect2, varscan2
- CACNB1 | c.1110A>C p.Q370H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100703569; called by muse, mutect2, varscan2
- CACNG3 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.085); catalogued as COSV50073959; called by muse, mutect2, varscan2
- CAD | c.6436C>T p.R2146* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99255714; called by mutect2, varscan2
- CADPS | c.2722G>T p.G908* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99340819; called by muse, mutect2, varscan2
- CADPS | c.2390T>G p.F797C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99340825; called by muse, varscan2
- CADPS | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs376619081, COSV51878134; called by muse, mutect2, varscan2
- CADPS | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1232809758, COSV99340829; called by muse, mutect2, varscan2
- CALCRL | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101131038, COSV66475467; called by mutect2, varscan2
- CALML4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750544784, COSV61206176; called by mutect2, varscan2
- CAMK1D | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV101123947; called by muse, mutect2, varscan2
- CAMSAP2 | c.2161C>A p.Q721K (on ENST00000236925 / NM_001297707.2; = p.Q710K on NM_203459.3) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV99374306; called by mutect2, varscan2
- CAMTA2 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV100772843; called by muse, mutect2, varscan2
- CAND1 | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101598290; called by muse, mutect2
- CAND1 | c.1446C>A p.F482L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); catalogued as COSV101607354; called by muse, mutect2, varscan2
- CAND2 | c.1984C>T p.R662W (on ENST00000456430 / NM_001162499.2; = p.R569W on NM_012298.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375533940; called by mutect2, varscan2
- CAND2 | c.3260G>A p.R1087Q (on ENST00000456430 / NM_001162499.2; = p.R970Q on NM_012298.3) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781451160, COSV55990798; called by muse, mutect2, varscan2
- CAPN13 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs565060477, COSV54429720; called by mutect2, varscan2
- CAPN6 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759834539, COSV60695723; called by mutect2, varscan2
- CARD6 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1418904058, COSV99621298; called by muse, varscan2
- CARMIL1 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.345); catalogued as COSV100278809; called by muse, mutect2, varscan2
- CARMIL2 | c.3598C>T p.R1200W | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs749504681, COSV54670266; called by mutect2, varscan2
- CASD1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs780697479, COSV51974019; called by mutect2, varscan2
- CASK | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs868537608, COSV59374892; called by mutect2, varscan2
- CASKIN1 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.783); catalogued as COSV100624423; called by muse, mutect2, varscan2
- CASP10 | c.1463G>T p.R488I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99787321; called by mutect2, varscan2
- CASP3 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.366); catalogued as COSV100395076; called by muse, mutect2, varscan2
- CASP5 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs1397399939, COSV52827519; called by muse, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASP8AP2 | c.2369T>G p.V790G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV99387552; called by muse, mutect2, varscan2
- CASQ1 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1221488091, COSV100927367; called by muse, mutect2, varscan2
- CASS4 | c.562-2A>G p.X188_splice | Splice Site (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100824918; called by muse, mutect2, varscan2
- CATSPER1 | c.1030T>G p.S344A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as rs377753488; called by mutect2, varscan2
- CATSPER2 | c.1179-1G>T p.X393_splice (on ENST00000321596 / NM_001282309.3; = p.R395I on NM_172095.4) | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100390987; called by mutect2, varscan2
- CATSPERB | c.1472G>T p.R491I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV56424364; called by muse, varscan2
- CATSPERB | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754792783, COSV56421740; called by mutect2, varscan2
- CATSPERE | c.115-1G>T p.X39_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV63676147; called by mutect2, varscan2
- CATSPERE | c.929T>G p.F310C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.613); catalogued as COSV100835372; called by muse, mutect2, varscan2
- CATSPERE | c.1512T>G p.Y504* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100835373; called by muse, mutect2, varscan2
- CAV2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs757765509, COSV99760864; called by mutect2, varscan2
- CAVIN3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV100392571; called by muse, mutect2, varscan2
- CBLB | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV51438509; called by muse, mutect2, varscan2
- CBLB | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs56312611, COSV99914290; called by mutect2, varscan2
- CBLL2 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100081748; called by mutect2, varscan2
- CBLL2 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs767538011, COSV100081752; called by mutect2, varscan2
- CBLN1 | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99535809, COSV99535819; called by muse, mutect2, varscan2
- CBLN4 | c.413A>C p.N138T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV99290745; called by muse, mutect2, varscan2
- CBX7 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779921144, COSV99334215; called by mutect2, varscan2
- CC2D2A | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101052932, COSV67504000; called by mutect2, varscan2
- CC2D2A | c.4334G>T p.R1445L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs113065116, COSV101052933, COSV67502234; called by mutect2, varscan2
- CCAR1 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771406; called by mutect2, varscan2
- CCAR1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56267515; called by muse, mutect2, varscan2
- CCDC110 | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100294173; called by muse, mutect2, varscan2
- CCDC110 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1033592210, COSV100294177; called by muse, mutect2, varscan2
- CCDC112 | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV101100531; called by muse, mutect2, varscan2
- CCDC113 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs568951247, COSV99541219; called by mutect2, varscan2
- CCDC116 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs199750621, COSV99489008; called by mutect2, varscan2
- CCDC117 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99968954; called by mutect2, varscan2
- CCDC120 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100900712; called by mutect2, varscan2
- CCDC120 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100900714; called by mutect2, varscan2
- CCDC122 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV55708664, COSV99865881; called by muse, varscan2
- CCDC14 | c.953G>A p.R318Q (on ENST00000488653; = p.R270Q on NM_022757.5) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766062605, COSV100113456; called by muse, mutect2, varscan2
- CCDC144A | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV100138700; called by mutect2, varscan2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by mutect2, varscan2
- CCDC15 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100777066; called by muse, mutect2, varscan2
- CCDC15 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.783); catalogued as COSV100776969; called by muse, mutect2, varscan2
- CCDC159 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV100712306; called by mutect2, varscan2
- CCDC18 | c.1020T>G p.I340M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100159947; called by muse, mutect2, varscan2
- CCDC181 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63156056, COSV63156341; called by muse, mutect2, varscan2
- CCDC189 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100079825; called by mutect2, varscan2
- CCDC191 | c.2767T>G p.S923A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99878751; called by muse, mutect2, varscan2
- CCDC191 | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99878753; called by muse, mutect2, varscan2
- CCDC34 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762461326, COSV100156695; called by mutect2, varscan2
- CCDC38 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99900113; called by mutect2, varscan2
- CCDC42 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1285551885, COSV99549927; called by muse, mutect2, varscan2
- CCDC50 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101165356; called by mutect2, varscan2
- CCDC50 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV66667794; called by mutect2, varscan2
- CCDC54 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53759935; called by muse, mutect2, varscan2
- CCDC59 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99810819; called by mutect2, varscan2
- CCDC63 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs536653873, COSV57528815; called by mutect2, varscan2
- CCDC66 | c.1055T>G p.I352S (on ENST00000394672 / NM_001353147.1; = p.I318S on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100413847; called by muse, mutect2, varscan2
- CCDC81 | c.1004G>A p.R335Q (on ENST00000445632 / NM_001156474.2; = p.R245Q on NM_021827.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs868030464, COSV53577858; called by mutect2, varscan2
- CCDC87 | c.1666T>G p.L556V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.039); catalogued as rs757137007, COSV100040181; called by muse, mutect2, varscan2
- CCDC88A | c.1951T>G p.L651V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99711185; called by muse, mutect2
- CCDC88A | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV55058141; called by muse, varscan2
- CCDC88A | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV55057279; called by muse, mutect2, varscan2
- CCL27 | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99426576; called by muse, mutect2, varscan2
- CCNB3 | c.537A>C p.K179N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99329849; called by muse, mutect2, varscan2
- CCNB3 | c.2145G>T p.E715D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV99329853; called by mutect2, varscan2
- CCND2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV99714466; called by muse, mutect2, varscan2
- CCNJ | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99796354; called by muse, varscan2
- CCNJ | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV99796358; called by muse, varscan2
- CCNL1 | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99904636; called by muse, mutect2, varscan2
- CCNL1 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55819193; called by muse, mutect2, varscan2
- CCR3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs1043285757, COSV100656740, COSV62463212; called by muse, mutect2, varscan2
- CCR5 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV52751470; called by mutect2, varscan2
- CCR9 | c.301C>T p.L101F (on ENST00000357632 / NM_031200.3; = p.L89F on NM_006641.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV100591785; called by muse, mutect2, varscan2
- CCSER1 | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100396013; called by mutect2, varscan2
- CD109 | c.844A>C p.K282Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV99754592; called by mutect2, varscan2
- CD109 | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV99754595; called by muse, mutect2, varscan2
- CD1B | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100939297; called by muse, mutect2, varscan2
- CD207 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV101338593; called by mutect2, varscan2
- CD209 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99214403; called by muse, varscan2
- CD209 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1403903788, COSV99214404; called by muse, mutect2, varscan2
- CD22 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs143516468; called by mutect2, varscan2
- CD2AP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199622885, COSV63763227; called by muse, mutect2, varscan2
- CD300E | c.339T>G p.D113E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV60789852; called by muse, mutect2, varscan2
- CD40 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as rs1031487767, COSV100953870; called by mutect2, varscan2
- CD40LG | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.257); catalogued as rs1252281345, CM016294, COSV65699146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD47 | c.607T>G p.S203A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV100790170; called by muse, varscan2
- CD72 | c.696C>A p.C232* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99427610; called by mutect2, varscan2
- CD84 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100246054; called by muse, mutect2, varscan2
- CDAN1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs764692459, COSV99142461; called by mutect2, varscan2
- CDC16 | c.1295T>A p.I432N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52959926, COSV52961913; called by muse, mutect2, varscan2
- CDC20B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1008892536, COSV57054773; called by muse, mutect2, varscan2
- CDC25A | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100207668; called by muse, mutect2, varscan2
- CDC34 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296436; called by muse, mutect2, varscan2
- CDC37L1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV101116654; called by muse, mutect2, varscan2
- CDC42BPA | c.2383A>G p.I795V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100506864; called by muse, mutect2, varscan2
- CDC42BPA | c.1298G>T p.R433M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100506866; called by muse, mutect2, varscan2
- CDC42BPB | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100775606; called by muse, mutect2, varscan2
- CDC42EP3 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763669525, COSV54873871; called by mutect2, varscan2
- CDC45 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99597032; called by muse, mutect2, varscan2
- CDH12 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772189448, COSV66392948; called by mutect2, varscan2
- CDH19 | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV100052335; called by muse, mutect2, varscan2
- CDH2 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV99298515; called by mutect2, varscan2
- CDH23 | c.8673C>A p.F2891L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.087); catalogued as COSV99823753; called by mutect2, varscan2
- CDH26 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54855719, COSV99722975; called by muse, mutect2, varscan2
- CDH4 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as rs757336738, COSV64650871; called by muse, mutect2, varscan2
- CDHR2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs766706774, COSV56138320; called by mutect2, varscan2
- CDK11B | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs766202713; called by mutect2, varscan2
- CDK13 | c.2414G>T p.G805V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99476085; called by muse, mutect2, varscan2
- CDK14 | c.871G>A p.E291K (on ENST00000380050 / NM_001287135.2; = p.E273K on NM_012395.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs144455762; called by mutect2, varscan2
- CDK15 | c.770C>T p.S257F (on ENST00000652192 / NM_001366386.2; = p.S206F on NM_139158.2) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99643694; called by mutect2, varscan2
- CDK5RAP2 | c.2542G>T p.E848* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as rs1372905733, COSV100575738; called by mutect2, varscan2
- CDK8 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101037623; called by muse, mutect2, varscan2
- CDKL1 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99367899; called by mutect2, varscan2
- CDKN1B | c.122T>G p.L41* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99964055; called by mutect2, varscan2
- CDON | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs761054118, COSV54995637; ClinVar: likely benign; called by mutect2, varscan2
- CDON | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV99701974; called by mutect2, varscan2
- CDON | c.640+1G>A p.X214_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as rs763917724, COSV54997499, COSV55004104; called by mutect2, varscan2
- CDS2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV100986042; called by mutect2, varscan2
- CDYL | c.710C>T p.A237V (on ENST00000328908 / NM_001368125.1; = p.A183V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs548377074, COSV100190127; called by mutect2, varscan2
- CEACAM8 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99747546, COSV99747853; called by mutect2, varscan2
- CELF6 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54717345, COSV54718491; called by mutect2, varscan2
- CELSR3 | c.3181A>G p.N1061D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99374930; called by muse, mutect2, varscan2
- CENPC | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1426281336, COSV99894428; called by muse, mutect2, varscan2
- CENPE | c.3156A>T p.K1052N | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.1); catalogued as COSV99479125; called by muse, mutect2, varscan2
- CEP126 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99681411; called by mutect2, varscan2
- CEP128 | c.3194G>T p.R1065I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99825985; called by mutect2, varscan2
- CEP128 | c.1886A>C p.K629T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99825987; called by muse, mutect2, varscan2
- CEP128 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV99383671; called by muse, varscan2
- CEP128 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs754026806, COSV53672760; called by muse, mutect2, varscan2
- CEP135 | c.2327C>A p.S776* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99954696, COSV99954893; called by muse, mutect2, varscan2
- CEP152 | c.4160A>C p.K1387T (on ENST00000380950 / NM_001194998.2; = p.K1331T on NM_014985.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100359145; called by muse, varscan2
- CEP162 | c.2536A>C p.I846L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV100003383; called by muse, mutect2, varscan2
- CEP170 | c.2216C>A p.S739Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100316326, COSV60513160; called by muse, mutect2, varscan2
- CEP19 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56359263; called by muse, mutect2, varscan2
- CEP192 | c.7174G>A p.E2392K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1298184979, COSV100380507; called by muse, mutect2, varscan2
- CEP250 | c.957T>G p.N319K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100699187; called by muse, mutect2, varscan2
- CEP250 | c.5797G>A p.A1933T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100699188; called by muse, mutect2, varscan2
- CEP290 | c.7339A>C p.K2447Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100469824; called by muse, mutect2, varscan2
- CEP290 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs753374614, COSV58353842, COSV58355012; called by muse, mutect2, varscan2
- CEP350 | c.6778G>T p.E2260* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100855223; called by muse, mutect2, varscan2
- CEP350 | c.8632T>G p.F2878V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100855224; called by mutect2, varscan2
- CEP68 | c.2107T>G p.L703V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561267; called by muse, mutect2, varscan2
- CEP70 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV99389572; called by muse, mutect2, varscan2
- CEP76 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100042977, COSV50871632; called by muse, mutect2, varscan2
- CEP78 | c.1592T>G p.F531C (on ENST00000424347 / NM_001349840.2; = p.F532C on NM_032171.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99450914; called by muse, mutect2
- CEP83 | c.747A>C p.Q249H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100353216; called by muse, mutect2, varscan2
- CEP85L | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs199692317, COSV100874369; called by mutect2, varscan2
- CEP89 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99993985; called by muse, mutect2, varscan2
- CEP95 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs370403874; called by muse, mutect2, varscan2
- CERKL | c.1238-1G>T p.X413_splice (on ENST00000339098 / NM_001030311.2; = p.X387_splice on NM_201548.5) | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100184190; called by mutect2, varscan2
- CERS6 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99987175, COSV99987746; called by muse, mutect2, varscan2
- CERT1 | c.1677A>C p.R559S (on ENST00000405807 / NM_001130105.1; = p.R431S on NM_005713.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99783727; called by muse, varscan2
- CES5A | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as COSV99307243; called by muse, mutect2, varscan2
- CETN1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs760929013, COSV59121106, COSV59121251; called by mutect2, varscan2
- CETN2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs373398188, COSV64743201; called by muse, mutect2, varscan2
- CFAP206 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs773938782, COSV99740046; called by mutect2, varscan2
- CFAP20DC | c.799C>A p.L267I (on ENST00000482387 / NM_001351530.2; = p.L142I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV99919520; called by mutect2, varscan2
- CFAP300 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101462489; called by mutect2, varscan2
- CFAP43 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99531005; called by muse, mutect2, varscan2
- CFAP45 | c.895A>C p.K299Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100928666; called by muse, mutect2, varscan2
- CFAP47 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1444898459, COSV99935831; called by mutect2, varscan2
- CFAP52 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV55345492; called by muse, mutect2, varscan2
- CFAP54 | c.8011A>C p.K2671Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100733327; called by muse, mutect2
- CFAP58 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs1387039931, COSV100866175; called by muse, mutect2, varscan2
- CFAP61 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1012240016, COSV99846635; called by mutect2, varscan2
- CFAP61 | c.3214T>C p.Y1072H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99846639; called by muse, mutect2, varscan2
- CFAP65 | c.3479G>A p.S1160N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100445920, COSV104419862; called by muse, mutect2, varscan2
- CFAP65 | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs151155794; called by mutect2, varscan2
- CFAP69 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100289788, COSV100290447; called by muse, mutect2, varscan2
- CFH | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV100661633; called by muse, mutect2, varscan2
- CFH | c.1538T>C p.V513A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100810171; called by muse, mutect2, varscan2
- CFH | c.3311-1G>A p.X1104_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100810173, COSV66406587; called by muse, mutect2, varscan2
- CFP | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV99901672; called by muse, mutect2, varscan2
- CFTR | c.3151A>C p.I1051L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as CM043473, COSV99139696; called by mutect2, varscan2
- CGAS | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370272118; called by muse, mutect2, varscan2
- CHCHD2 | c.444C>T p.N148= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as rs758536733, COSV68169866; called by mutect2, varscan2
- CHD1 | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV52336555, COSV52342038; called by mutect2, varscan2
- CHD1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99399886; called by mutect2, varscan2
- CHD2 | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100560399; called by muse, mutect2
- CHD2 | c.2160G>T p.E720D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as COSV101245978; called by muse, mutect2, varscan2
4,902 further variants in this file (3,721 protein-altering or splice-affecting, 1,029 silent, 152 other) are not listed here.
